CCDI case PBCJHF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/17c47297-1730-47a7-b9d0-a833ed8a0d38

Demographics
Sex at birth: male; Race: white.

Biospecimens (3 samples)
- Sample 0DTB88: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTB8L: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DTB8V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
